Somatic mutation profile of tumor specimen ALCH-B2V3-TTP1-A (aliquot ALCH-B2V3-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2V3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,002 days).
Specimen ALCH-B2V3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aab4fe62-a09a-4c4b-8497-3d3aaa8592fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V3-NB1-A (Blood Derived Normal), aliquot ALCH-B2V3-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de129eb0-0340-4de9-92fd-138c3557818d

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 18, Intron 5, Nonsense Mutation 3, 3'UTR 3, Frame Shift Del 2, RNA 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 242/401 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 72/154 reads (47%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 19/693 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- ALX4 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200122905, COSV61326470; called by muse, mutect2, varscan2
- AMPH | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100340628, COSV57735667, COSV57745382; called by muse, mutect2, varscan2
- ANKRD50 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476247796, COSV72385476; called by muse, mutect2, varscan2
- ATAD2B | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs1397115881; called by muse, mutect2, varscan2
- CDH22 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1392987280, COSV64840217; called by muse, mutect2, varscan2
- CKAP5 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 68/448 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56374528; called by muse, mutect2, varscan2
- COL6A3 | c.6175G>A p.G2059S | Missense Mutation (SNP) | VAF 214/690 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758124326, CM1310900; called by muse, mutect2, varscan2
- DRP2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 77/412 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs201156733, COSV65811862; called by muse, mutect2, varscan2
- FIBCD1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs945498576, COSV53395796; called by muse, mutect2
- GAL3ST2 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1340703846; called by muse, mutect2
- HR | c.2042G>T p.W681L | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as rs772822146; called by muse, mutect2, varscan2
- MGAT3 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 109/439 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1260975397; called by muse, mutect2, varscan2
- NOS1 | c.3145G>A p.V1049M | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178704994; called by muse, mutect2, varscan2
- NPTXR | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs755394676, COSV60729373; called by muse, mutect2, varscan2
- PCDHA6 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 75/499 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs1554131099; called by muse, mutect2, varscan2
- PDLIM7 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs768479307; called by muse, mutect2, varscan2
- PIEZO2 | c.7002A>T p.L2334F | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767953271; called by muse, varscan2
- PRSS38 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs773602792; called by muse, mutect2, varscan2
- RYR2 | c.5821C>T p.R1941C | Missense Mutation (SNP) | VAF 84/511 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as rs754811291; called by muse, mutect2, varscan2
- SCAP | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV99652474; called by muse, mutect2, varscan2
- SLC6A5 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 516/1207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766837791, COSV54229114; called by muse, mutect2, varscan2
- TOGARAM1 | c.1792G>T p.G598W | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs373580836, COSV61888736; called by muse, mutect2, varscan2
- TRPC4 | c.1455C>A p.N485K | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV58996855; called by muse, mutect2, varscan2
- YRDC | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs1440926229; called by muse, varscan2
- ZSCAN10 | c.1739G>A p.R580H (on ENST00000252463; = p.R635H on NM_032805.3) | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1430087984; called by muse, mutect2, varscan2
- ABCC11 | c.4048A>G p.N1350D | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG1L | c.104T>C p.F35S | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AMELX | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- APBA3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- BUB1 | c.1969A>G p.I657V | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CCNB3 | c.2640G>C p.L880F | Missense Mutation (SNP) | VAF 102/481 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNNM4 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 11/380 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- CPXM1 | c.1893C>A p.D631E | Missense Mutation (SNP) | VAF 104/525 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTAG2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- CYP4F11 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ERVH48-1 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FAT3 | c.5296G>T p.A1766S | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBLL1 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 30/804 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IQGAP3 | c.4768C>T p.Q1590* | Nonsense Mutation (SNP) | VAF 56/522 reads (11%) | called by muse, varscan2
- ITM2A | c.276dup p.D93* | Frame Shift Ins (INS) | VAF 100/605 reads (17%) | called by mutect2, pindel, varscan2
- KCNH8 | c.2680C>G p.L894V | Missense Mutation (SNP) | VAF 108/351 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KIR3DL3 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, varscan2
- MBTPS2 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 118/665 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MOGS | c.280_287del p.L94Gfs*36 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- MUC5B | c.7202A>G p.N2401S | Missense Mutation (SNP) | VAF 65/864 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- NOXO1 | c.451C>G p.L151V (on ENST00000397280 / NM_172168.3; = p.L145V on NM_144603.4) | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- PAF1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 129/497 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PATZ1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2
- PLCH1 | c.580G>A p.E194K (on ENST00000340059 / NM_001130960.2; = p.E206K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PTPRN | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.6505C>G p.L2169V | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, varscan2
- RHOT1 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SETD1B | c.156del p.Q53Sfs*53 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by pindel, varscan2
- SIAH3 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2
- SLC6A11 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 125/545 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SMC1A | c.2286G>C p.M762I | Missense Mutation (SNP) | VAF 72/900 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STK40 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TM9SF2 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TMEM74 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TRIM66 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WNT11 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- ZFHX4 | c.8196C>A p.Y2732* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- ZNF730 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2
- ZNF804A | c.3419G>T p.R1140I | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF804A | c.3420A>T p.R1140S | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACVRL1 | c.1362G>T p.R454= | Silent (SNP) | VAF 78/215 reads (36%) | called by muse, mutect2, varscan2
- ATP11C | c.2532A>T p.A844= | Silent (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- DRC1 | c.1596C>T p.F532= | Silent (SNP) | VAF 62/230 reads (27%) | called by muse, mutect2, varscan2
- H1-5 | c.426C>G p.A142= | Silent (SNP) | VAF 107/603 reads (18%) | called by muse, mutect2, varscan2
- IQGAP3 | c.4686C>T p.V1562= | Silent (SNP) | VAF 72/564 reads (13%) | called by muse, varscan2
- KIF13B | c.2910C>T p.I970= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs1381618918, COSV72954595; called by muse, mutect2, varscan2
- LAMA5 | c.9609C>T p.Y3203= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as rs756426753, COSV53352950; called by muse, mutect2
- MAP1B | c.3984T>A p.T1328= | Silent (SNP) | VAF 116/236 reads (49%) | called by muse, mutect2, varscan2
- MORC2 | c.1308C>T p.Y436= (on ENST00000397641 / NM_001303256.3; = p.Y374= on NM_014941.3) | Silent (SNP) | VAF 82/332 reads (25%) | catalogued as rs768240412; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB3 | c.84C>T p.S28= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs782670769, COSV50579952; called by mutect2, varscan2
- PDE1C | c.1785G>A p.E595= | Silent (SNP) | VAF 19/489 reads (4%) | catalogued as COSV58527576, COSV58534606; called by muse, mutect2
- PLEC | c.11352C>G p.L3784= (on ENST00000322810 / NM_201380.4; = p.L3674= on NM_000445.5) | Silent (SNP) | VAF 92/833 reads (11%) | called by muse, mutect2, varscan2
- PLK3 | c.219C>T p.F73= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as rs759735743, COSV64728444; called by muse, mutect2, varscan2
- PRKDC | c.2272C>T p.L758= | Silent (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- ROBO2 | c.1596T>C p.D532= | Silent (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- SAMD9L | c.3249C>T p.F1083= | Silent (SNP) | VAF 25/321 reads (8%) | called by muse, mutect2
- VGF | c.156G>A p.K52= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs780164922; called by muse, mutect2, varscan2
- ZNF780A | c.825A>G p.K275= | Silent (SNP) | VAF 156/259 reads (60%) | called by muse, mutect2, varscan2
- ACACA | c.*23G>T | 3'UTR (SNP) | VAF 105/377 reads (28%) | catalogued as rs748601714; called by muse, mutect2, varscan2
- IMPA2 | c.231-1529_231-1485del | Intron (DEL) | VAF 42/484 reads (9%) | called by mutect2, pindel
- MAGEA5 | n.177A>G | RNA (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+976G>T | Intron (SNP) | VAF 34/150 reads (23%) | catalogued as rs979500953; called by muse, mutect2, varscan2
- MYO1F | c.1269+14C>A | Intron (SNP) | VAF 93/159 reads (58%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.583C>G | RNA (SNP) | VAF 47/418 reads (11%) | called by muse, mutect2, varscan2
- PHETA1 | c.*724C>T | 3'UTR (SNP) | VAF 115/399 reads (29%) | called by muse, mutect2, varscan2
- PLXDC1 | c.*4319C>T | 3'UTR (SNP) | VAF 65/261 reads (25%) | catalogued as rs781073291; called by muse, mutect2, varscan2
- PTDSS2 | c.182+810G>C | Intron (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2
- SEPTIN3 | c.1012-9C>T | Intron (SNP) | VAF 104/204 reads (51%) | called by muse, mutect2, varscan2
